CCDI case PBCJMS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/79c73343-7305-412e-a259-a1a789fb0e44

Demographics
Sex at birth: male.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9161/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.6 years (1,696 days).

Biospecimens (3 samples)
- Sample 0DTC5Q: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTC5Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTC65: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
